Somatic mutation profile of tumor specimen TARGET-40-NAAGJU-01A (aliquot TARGET-40-NAAGJU-01A-01D) from TARGET case TARGET-40-NAAGJU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.8 years (4,671 days).
Specimen TARGET-40-NAAGJU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 244d0a54-16c0-4e69-bb3a-98b253ed4fc3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJU-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/995aadba-0862-4986-a26f-2078fcc10490

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP6R2 | c.2596G>A p.G866S (on ENST00000216061 / NM_001365836.1; = p.G832S on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs367629519; called by muse, varscan2
- SLX4 | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF236 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.04); called by muse, mutect2, varscan2
